TCGA case TCGA-49-4486 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/61c655ec-52b5-453f-a6cc-b2aba445b027

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 72 years; Vital status: Dead; Days to death: 2,318 days (6.3 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 72.3 years (26,415 days); Year of diagnosis: 1992; AJCC staging edition: 3rd; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 77.9 years (28,460 days); Days to diagnosis: 2,045 days (5.6 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Day 2,045 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 2,045 days (5.6 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 2,318 days (6.3 years); Disease response: With Tumor.
- Karnofsky performance status: 60; ECOG performance status: 2; Timepoint: Other.
- ECOG performance status: 1; Timepoint: Other.

Other clinical attributes
- FEV1/FVC after bronchodilator (%): 69; FEV1/FVC before bronchodilator (%): 77; FEV1 after bronchodilator (% of reference): 96; FEV1 before bronchodilator (% of reference): 108.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 17.5; Tobacco smoking onset year: 1932; Tobacco smoking quit year: 1967.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-49-4486-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.6; Intermediate dimension: 0.6; Shortest dimension: 0.6.
  Slide TCGA-49-4486-01A-01-TS1: Section location: Top; Percent tumor cells: 94; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 5.
  Slide TCGA-49-4486-01A-01-BS1: Section location: Bottom; Percent tumor cells: 94; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 5.
- Sample TCGA-49-4486-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Lower; Pulmonary function test indicator: Yes.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,318 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,318 days; disease-free interval: event (new tumor event after initially disease-free), 2,045 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,045 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-49-4486-01A-01D-1204-01): tumor purity 0.73, ploidy 2.08, whole-genome doublings 0.
